Gene-level copy-number profile of tumor specimen TARGET-10-PATMTV-09A from TARGET case TARGET-10-PATMTV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.1 years (4,045 days).
Specimen TARGET-10-PATMTV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.b78d1d10-f88e-5d39-99bf-b074cf338915.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATMTV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 393 have no estimate.
https://portal.gdc.cancer.gov/files/228dcefb-0fe7-46d1-863e-4559332caea3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 2,545; copy number 2: 57,343; copy number 3: 1; copy number 4: 321; copy number 6: 4.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:31,367,057–31,376,088, 1 gene (within-gene range 0–2): AL671883.3.
- chr7:38,291,616–38,340,998, 10 genes: TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes: TRGV5P, TRGV5, TRGV4.
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:135,181,308–135,260,933, 4 genes, copy number 6: MYB, MYB-AS1, MIR548A2, AL023693.1.

Autosomal genes at a single copy (total copy number 1): 157. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
